Somatic mutation profile of tumor specimen C3L-00989-03 (aliquot CPT0122890006) from CPTAC case C3L-00989, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 57.2 years (20,895 days).
Specimen C3L-00989-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdb02533-c69d-4006-a5b7-8d25069b4393.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00989-31 (Blood Derived Normal), aliquot CPT0124720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48978519-3514-4891-82cd-4c001065fc31

The open-access MAF lists 1,019 somatic variants for this specimen: 659 protein-altering or splice-affecting, 324 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 598, Silent 324, Nonsense Mutation 41, Intron 19, Splice Region 12, 3'UTR 7, 5'Flank 5, Splice Site 3, Frame Shift Ins 2, Frame Shift Del 2, 5'UTR 2, 3'Flank 2.

Variants (750 of 1,019; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 37/269 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 34/367 reads (9%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- WRN | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 53/289 reads (18%) | catalogued as rs774765029, CM961464, COSV53297187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs867031783, COSV60911484; called by muse, mutect2, varscan2
- ABCC4 | c.3200C>T p.S1067L | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV65312878; called by muse, mutect2, varscan2
- ABCG2 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs529212191, COSV99420023; called by muse, mutect2, varscan2
- ADAM7 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs910236169, COSV51535730; called by muse, mutect2, varscan2
- ADAMTS5 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 68/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99537421; called by muse, mutect2, varscan2
- ADCY8 | c.2746G>A p.G916R | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99652256; called by muse, mutect2, varscan2
- AFAP1L2 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100412535; called by muse, mutect2, varscan2
- AL645922.1 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV54961014; called by muse, mutect2, varscan2
- AMHR2 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 66/403 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302954517, COSV57685575; called by muse, mutect2, varscan2
- AMPD3 | c.599C>T p.P200L (on ENST00000396553 / NM_001025389.2; = p.P209L on NM_000480.3) | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV67329991; called by muse, mutect2, varscan2
- ANK3 | c.9763C>T p.P3255S | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs867013789, COSV99780936; called by muse, mutect2, varscan2
- ANK3 | c.8956C>T p.P2986S | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV55073837; called by muse, mutect2, varscan2
- ANK3 | c.7930G>A p.D2644N | Missense Mutation (SNP) | VAF 67/467 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); catalogued as rs756767147; called by muse, mutect2, varscan2
- ANKRD11 | c.5996C>T p.P1999L | Missense Mutation (SNP) | VAF 93/601 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs756815181; called by muse, mutect2, varscan2
- ANKRD17 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 64/440 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1312095685; called by mutect2, varscan2
- ANKRD6 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.626); catalogued as COSV100329472; called by muse, mutect2, varscan2
- ARFGEF3 | c.3388G>A p.D1130N | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.045); catalogued as COSV52452461; called by muse, mutect2, varscan2
- ARHGAP21 | c.3754C>T p.P1252S | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.952); catalogued as COSV100256566; called by muse, mutect2, varscan2
- ARHGAP6 | c.2732G>A p.G911E (on ENST00000337414 / NM_013427.3; = p.G708E on NM_013423.3) | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV57294525; called by muse, mutect2, varscan2
- ARHGEF18 | c.2686G>A p.E896K (on ENST00000359920 / NM_001130955.2; = p.E792K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/512 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as rs1190221161; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ATG16L1 | c.1447C>T p.R483* (on ENST00000392017 / NM_030803.7; = p.R464* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 34/255 reads (13%) | catalogued as COSV100731192; called by muse, mutect2, varscan2
- ATP13A1 | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 83/534 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV99365732; called by muse, mutect2, varscan2
- ATP2C2 | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.927); catalogued as rs1240035375; called by muse, mutect2, varscan2
- AXDND1 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs773212839, COSV62642775; called by muse, varscan2
- BAHCC1 | c.7628C>T p.S2543L | Missense Mutation (SNP) | VAF 56/443 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1303261568; called by muse, mutect2, varscan2
- BBS9 | c.2330C>T p.S777F (on ENST00000242067 / NM_001348036.1; = p.S737F on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99625690; called by muse, mutect2, varscan2
- BICC1 | c.2768G>A p.R923K | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100874905; called by muse, mutect2, varscan2
- BMP1 | c.2701G>A p.G901S | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.229); catalogued as rs769359150, COSV100114478; called by muse, mutect2, varscan2
- BMX | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.659); catalogued as COSV59590137; called by muse, mutect2, varscan2
- BRD3 | c.2158T>C p.S720P | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as rs1156556118; called by muse, mutect2, varscan2
- CACNA1I | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 59/382 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV60804896; called by muse, mutect2, varscan2
- CACNA1S | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763147200; called by muse, mutect2, varscan2
- CAND2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 79/341 reads (23%) | catalogued as rs1364539269, COSV99929889; called by muse, mutect2, varscan2
- CASR | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 95/399 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs768228172; called by muse, mutect2, varscan2
- CATSPERB | c.2133G>A p.W711* | Nonsense Mutation (SNP) | VAF 77/510 reads (15%) | catalogued as COSV56434562; called by muse, mutect2, varscan2
- CCDC158 | c.2930G>A p.R977K | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV101187430; called by muse, mutect2, varscan2
- CCDC189 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1567267790; called by muse, mutect2, varscan2
- CCDC60 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 73/459 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100555529; called by muse, mutect2, varscan2
- CCDC62 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 68/422 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV53431642; called by muse, mutect2, varscan2
- CCL22 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs867871956, COSV54659988, COSV54660213; called by muse, mutect2, varscan2
- CD46 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as rs774372135; called by muse, mutect2, varscan2
- CDH13 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as rs768668842, COSV51844595; called by muse, mutect2, varscan2
- CDH18 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.763); catalogued as rs1461706836; called by muse, mutect2, varscan2
- CELA3B | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 78/425 reads (18%) | catalogued as rs767682172; called by muse, mutect2, varscan2
- CFAP69 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1410333272; called by muse, mutect2, varscan2
- CHST15 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs150299035; called by muse, mutect2, varscan2
- CLSTN3 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 37/284 reads (13%) | catalogued as COSV56940036; called by muse, mutect2, varscan2
- CMTM8 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs1392994729; called by muse, mutect2
- CMYA5 | c.8818C>T p.Q2940* | Nonsense Mutation (SNP) | VAF 83/485 reads (17%) | catalogued as rs571512200, COSV71405932; called by muse, mutect2, varscan2
- CNGB1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.054); catalogued as COSV51898741; called by muse, mutect2, varscan2
- CNTNAP5 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV70498906; called by muse, mutect2, varscan2
- CNTNAP5 | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); catalogued as rs1188073110, COSV70482214, COSV70483142; called by muse, mutect2, varscan2
- COL11A1 | c.5069C>T p.S1690F | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62199099, COSV62200534; called by muse, mutect2, varscan2
- COL1A1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 84/520 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99868431; called by muse, mutect2, varscan2
- COL6A2 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs1273249543, COSV56003295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.6041C>T p.S2014F (on ENST00000312481; = p.S2010F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99592986; called by muse, mutect2, varscan2
- COLEC10 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100250670; called by muse, mutect2, varscan2
- CPA6 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 73/428 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs375296440, COSV52725616; called by muse, mutect2, varscan2
- CPA6 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52729567; called by muse, mutect2, varscan2
- CSF3R | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779227407, COSV58966490; called by muse, mutect2, varscan2
- CSMD3 | c.4069C>T p.P1357S (on ENST00000297405 / NM_001363185.1; = p.P1253S on NM_052900.3) | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52108152; called by muse, mutect2, varscan2
- CTAGE6 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV69918226, COSV69919151; called by mutect2, varscan2
- CTNND2 | c.1304G>A p.R435K | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1463267965, COSV100481382; called by muse, mutect2, varscan2
- CXCR1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 65/410 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as rs140803476; called by muse, mutect2, varscan2
- CYLC2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 73/472 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1472871675, COSV66336839; called by muse, mutect2, varscan2
- DAXX | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 93/566 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56468340; called by muse, mutect2, varscan2
- DCC | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs868536178; called by muse, mutect2, varscan2
- DCDC1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as rs201815238; called by muse, mutect2, varscan2
- DCLK3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 43/524 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1273313698; called by muse, mutect2
- DEFB129 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 59/435 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1190758754; called by muse, mutect2, varscan2
- DES | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144057476; called by muse, mutect2, varscan2
- DNAH11 | c.6535G>A p.G2179R | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1043191855; called by muse, mutect2, varscan2
- DNAH3 | c.10616C>T p.A3539V | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54549492; called by muse, mutect2, varscan2
- DNAH7 | c.10915G>A p.E3639K | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs762932607; called by muse, mutect2
- DNAH7 | c.6101C>T p.P2034L | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765491; called by muse, mutect2, varscan2
- DPP6 | c.1134G>A p.M378I (on ENST00000377770 / NM_001364500.2; = p.M316I on NM_001936.5) | Missense Mutation (SNP) | VAF 63/306 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as rs1389768773; called by muse, mutect2, varscan2
- DRD1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 70/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757759969, COSV67104946; called by muse, mutect2, varscan2
- DSG1 | c.2600G>A p.R867K | Missense Mutation (SNP) | VAF 80/494 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57138644; called by muse, mutect2, varscan2
- DUOXA1 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 67/382 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs747056739; called by muse, mutect2, varscan2
- DYNC2H1 | c.7730G>A p.G2577E | Missense Mutation (SNP) | VAF 62/371 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs1182674566; called by muse, mutect2, varscan2
- E2F3 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 130/570 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as rs1322442077; called by muse, mutect2, varscan2
- E2F5 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV56274350; called by muse, mutect2, varscan2
- EMB | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV100296603; called by muse, mutect2, varscan2
- EPPK1 | c.1789G>A p.G597S | Missense Mutation (SNP) | VAF 88/475 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.022); catalogued as COSV101599937; called by muse, mutect2, varscan2
- ETV1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1159395009, COSV54146212; called by muse, mutect2, varscan2
- EXPH5 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.331); catalogued as rs115380502, COSV56207367; called by muse, mutect2, varscan2
- F9 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54380173; called by muse, mutect2, varscan2
- FAM110A | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 23/640 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1294212465; called by muse, mutect2
- FAM13C | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 68/471 reads (14%) | catalogued as rs753412766, COSV53255959; called by muse, mutect2, varscan2
- FAM221B | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 64/390 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs765763890; called by muse, mutect2, varscan2
- FAM234B | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 209/643 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs866520971, COSV52194119; called by muse, mutect2, varscan2
- FAM234B | c.158C>G p.P53R | Missense Mutation (SNP) | VAF 211/646 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as COSV52192547, COSV52198581; called by muse, mutect2, varscan2
- FAM83B | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.5); catalogued as COSV60921404; called by muse, mutect2, varscan2
- FAT1 | c.13250C>T p.P4417L | Missense Mutation (SNP) | VAF 96/494 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101499160; called by muse, mutect2, varscan2
- FAT3 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53115002, COSV53159803; called by muse, mutect2, varscan2
- FAT4 | c.8479G>A p.G2827R | Missense Mutation (SNP) | VAF 57/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100628944; called by muse, mutect2, varscan2
- FAT4 | c.13282C>T p.P4428S | Missense Mutation (SNP) | VAF 73/470 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs771543271, COSV58708583; called by muse, mutect2, varscan2
- FBN2 | c.6880G>A p.D2294N | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52510691; called by muse, mutect2, varscan2
- FGA | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 86/458 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs763974301; called by muse, mutect2, varscan2
- FGF5 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779008349; called by muse, mutect2, varscan2
- FLG | c.6682G>A p.G2228R | Missense Mutation (SNP) | VAF 80/474 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.591); catalogued as COSV100912436; called by muse, mutect2, varscan2
- FMO1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV61444890; called by muse, mutect2, varscan2
- FMR1 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs376588908, COSV54424392; called by muse, mutect2, varscan2
- FNDC1 | c.5675G>A p.G1892E | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747424234; called by muse, mutect2, varscan2
- FOCAD | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as rs376862300; called by muse, mutect2, varscan2
- FPR2 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 102/534 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749741937, COSV100389176; called by muse, mutect2, varscan2
- FREM3 | c.5680G>A p.E1894K | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as rs200314721; called by muse, mutect2, varscan2
- FSIP2 | c.10591C>T p.Q3531* | Nonsense Mutation (SNP) | VAF 25/304 reads (8%) | catalogued as rs868173066; called by muse, mutect2
- FTHL17 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV100784357, COSV63267036; called by muse, mutect2, varscan2
- FYB2 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1557600991, COSV58586757; called by muse, mutect2, varscan2
- GAS2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1280902910, COSV53413022; called by muse, mutect2, varscan2
- GFRAL | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs749227939, COSV61229928; called by muse, mutect2, varscan2
- GHR | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50106373; called by muse, mutect2, varscan2
- GLMP | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 78/429 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs541609519; called by muse, mutect2, varscan2
- GLYATL3 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 45/221 reads (20%) | catalogued as rs570894431; called by muse, mutect2, varscan2
- GOLGA6L6 | c.477G>A p.W159* | Nonsense Mutation (SNP) | VAF 54/247 reads (22%) | catalogued as rs1407016443; called by muse, mutect2, varscan2
- GPR1 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 96/492 reads (20%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.961); catalogued as rs1467692061; called by muse, varscan2
- GPRC6A | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 64/394 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100114468; called by muse, mutect2, varscan2
- GRID2IP | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 74/466 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV71697369; called by muse, mutect2, varscan2
- GRIN2A | c.3445G>A p.D1149N | Missense Mutation (SNP) | VAF 75/473 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV58026335; called by muse, mutect2, varscan2
- HCAR2 | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 36/698 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100186674; called by muse, mutect2
- HCAR3 | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs753724916; called by muse, mutect2, varscan2
- HDAC9 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1042313151, COSV101286773; called by muse, mutect2, varscan2
- HDAC9 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV101286812, COSV67769445; called by muse, mutect2, varscan2
- HIVEP3 | c.3982C>T p.P1328S | Missense Mutation (SNP) | VAF 72/536 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56021556; called by muse, mutect2, varscan2
- HORMAD1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs746368595, COSV59270334; called by muse, mutect2, varscan2
- HS3ST2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1403875165, COSV54469515; called by muse, mutect2, varscan2
- HSF5 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 79/439 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV60419495; called by muse, mutect2, varscan2
- HSPG2 | c.5993C>T p.P1998L | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1433835093; called by muse, mutect2, varscan2
- HYDIN | c.7534G>A p.E2512K | Missense Mutation (SNP) | VAF 111/748 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1485839474; called by muse, mutect2, varscan2
- HYKK | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 39/228 reads (17%) | catalogued as rs759377784; called by muse, mutect2, varscan2
- IKZF2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 75/398 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV59583216; called by muse, mutect2, varscan2
- IL18RAP | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 52/545 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs143234495, COSV51828877, COSV99961891; called by muse, mutect2
- IL20RA | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs776649311; called by muse, mutect2, varscan2
- INPP5J | c.1695G>A p.M565I (on ENST00000331075 / NM_001284285.2; = p.M197I on NM_001002837.2) | Missense Mutation (SNP) | VAF 75/402 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as rs1249299074; called by muse, mutect2, varscan2
- IQCA1L | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 73/448 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1353494196; called by muse, mutect2, varscan2
- IRF8 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99236218; called by muse, mutect2, varscan2
- ITPKB | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 65/424 reads (15%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs763972727; called by muse, mutect2, varscan2
- IVL | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 86/491 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.071); catalogued as rs267598043; called by muse, mutect2, varscan2
- KCNB2 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 84/524 reads (16%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.175); catalogued as rs867236998, COSV73052586; called by muse, mutect2, varscan2
- KCNT1 | c.1564G>A p.E522K (on ENST00000488444; = p.E541K on NM_020822.3) | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs753040489; called by muse, mutect2, varscan2
- KDR | c.3365G>A p.G1122E | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55778076; called by muse, mutect2, varscan2
- KIF13A | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 45/458 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52462204; called by muse, mutect2, varscan2
- KLF12 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV66573281; called by muse, mutect2, varscan2
- KLHDC7A | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 87/519 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1185788855, COSV101272847; called by muse, mutect2, varscan2
- KRBA1 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 65/427 reads (15%) | catalogued as rs778637029, COSV55442682; called by muse, mutect2, varscan2
- KRT1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 49/343 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52868341; called by muse, mutect2, varscan2
- KRT2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752147255; called by muse, mutect2, varscan2
- LAMA3 | c.9404C>T p.S3135L (on ENST00000313654 / NM_198129.4; = p.S1526L on NM_000227.6) | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs267605132, COSV99335067; called by muse, mutect2, varscan2
- LAMP5 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99855504; called by muse, mutect2, varscan2
- LDLRAD4 | c.183G>A p.S61= | Splice Region (SNP) | VAF 38/274 reads (14%) | catalogued as rs1471206600, COSV63335347, COSV63341999; called by muse, varscan2
- LEXM | c.924G>A p.L308= | Splice Region (SNP) | VAF 46/292 reads (16%) | catalogued as rs1370263330; called by muse, mutect2, varscan2
- LMOD2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 64/483 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71755717; called by muse, varscan2
- LNX1 | c.1541C>T p.P514L (on ENST00000263925 / NM_001126328.3; = p.P418L on NM_032622.2) | Missense Mutation (SNP) | VAF 67/416 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs1560617750; called by muse, mutect2, varscan2
- LONP1 | c.1504C>T p.L502= | Splice Region (SNP) | VAF 48/293 reads (16%) | catalogued as rs750418547; called by muse, mutect2, varscan2
- LPA | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 95/472 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as rs1235478157; called by muse, mutect2, varscan2
- LRRC3 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 80/489 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1363125869; called by muse, mutect2, varscan2
- LRRC7 | c.2689C>T p.P897S (on ENST00000651989 / NM_001370785.2; = p.P864S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50481074; called by muse, mutect2, varscan2
- LRRD1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV58468872; called by muse, mutect2, varscan2
- LRRTM4 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 30/377 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV69140383; called by muse, mutect2
- MAGEA4 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 149/359 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs746017699, COSV52343660; called by muse, mutect2, varscan2
- MAGEB1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV66775620; called by muse, mutect2, varscan2
- MAGEC1 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV53575204; called by muse, mutect2, varscan2
- MAGI1 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 47/393 reads (12%) | catalogued as COSV58312476; called by muse, mutect2, varscan2
- MAP7D2 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 71/235 reads (30%) | catalogued as rs945525875, COSV65529783; called by muse, mutect2, varscan2
- MBOAT2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as rs1414149743; called by muse, mutect2, varscan2
- MECOM | c.2983G>A p.E995K (on ENST00000468789 / NM_001105078.4; = p.E1183K on NM_004991.4) | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99245528; called by muse, mutect2, varscan2
- MICB | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs772520548, COSV52857399; called by muse, mutect2, varscan2
- MLH1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs63750866, CD065763, CM970955, CS010557; called by muse, mutect2, varscan2
- MMP26 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56173901; called by muse, varscan2
- MPPED1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 62/438 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs757160081; called by muse, mutect2, varscan2
- MSH4 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs765416575; called by muse, mutect2, varscan2
- MTUS2 | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV70917016; called by muse, mutect2, varscan2
- MUC16 | c.36287C>T p.S12096F | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67440921, COSV67465048; called by muse, mutect2
- MUC16 | c.18940G>A p.E6314K | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.549); catalogued as COSV67457320; called by muse, mutect2, varscan2
- MYBPC2 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.584); catalogued as rs201632456; called by muse, mutect2, varscan2
- MYH15 | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs765296436, COSV56317792; called by muse, mutect2, varscan2
- MYO3A | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1391334286, COSV56319792; called by muse, mutect2, varscan2
- NACA2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 106/584 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs61739272; called by muse, mutect2, varscan2
- NCR1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 96/664 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs369920502; called by muse, mutect2, varscan2
- NCR1 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 94/662 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.295); catalogued as COSV52556173; called by muse, mutect2, varscan2
- NELFA | c.1117C>T p.P373S (on ENST00000542778; = p.P362S on NM_005663.5) | Missense Mutation (SNP) | VAF 113/589 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs1057035677; called by muse, mutect2, varscan2
- NFKBIE | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 101/540 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV51487728; called by muse, mutect2, varscan2
- NLRP11 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs367712953; called by muse, mutect2, varscan2
- NLRP3 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 84/406 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs180177464, CM068199, COSV60227851; ClinVar: not provided; called by muse, mutect2, varscan2
- NLRP8 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52593385; called by muse, mutect2, varscan2
- NME8 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 69/381 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs773058604; called by muse, mutect2, varscan2
- NOL4 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs868743933, COSV52344835; called by muse, mutect2, varscan2
- NOX3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs527483156, COSV50157240; called by muse, mutect2
- NWD1 | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 74/457 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs772901986; called by muse, mutect2, varscan2
- NYX | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 117/330 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV61180585; called by muse, mutect2, varscan2
- OGG1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV57354976; called by muse, mutect2, varscan2
- OR10A2 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 67/508 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745392336, COSV56298998; called by muse, mutect2
- OR10AC1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 84/630 reads (13%) | SIFT tolerated, low confidence (0.25); catalogued as rs1440434103; called by muse, mutect2, varscan2
- OR13F1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 78/378 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.192); catalogued as rs140352060; called by muse, mutect2, varscan2
- OR2AK2 | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 69/432 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV63552754, COSV63560644; called by muse, mutect2, varscan2
- OR2J3 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 51/430 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1308459445, COSV101013667, COSV65848677, COSV99058513; called by muse, mutect2, varscan2
- OR2T10 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs868867209, COSV100393604; called by muse, mutect2, varscan2
- OR2W1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 50/615 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101013905; called by muse, mutect2
- OR4A15 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 67/445 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.443); catalogued as rs1246693971, COSV59034117, COSV59037860; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 70/430 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR4K5 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 59/548 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV60002313; called by muse, mutect2, varscan2
- OR4K5 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 59/610 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60002718; called by muse, mutect2
- OR4M1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 85/805 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.367); catalogued as rs201377742, COSV100270969, COSV60060509; called by muse, varscan2
- OR4X1 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs1278579307, COSV60723193; called by muse, mutect2, varscan2
- OR51E1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 80/477 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.077); catalogued as rs866362558; called by muse, mutect2, varscan2
- OR51S1 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 78/513 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV59059213; called by muse, mutect2, varscan2
- OR7D4 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 62/382 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1208575353, COSV58072206; called by muse, varscan2
- OR8B12 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 75/478 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as COSV60911080; called by muse, mutect2, varscan2
- OR8B8 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 79/489 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1348728892, COSV100045379; called by muse, varscan2
- OR8B8 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.077); catalogued as rs1234803570; called by muse, varscan2
- OR8J1 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1045267197, COSV57317872; called by muse, mutect2, varscan2
- OTOGL | c.5159C>T p.S1720L (on ENST00000547103; = p.S1711L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV54023524; called by muse, mutect2, varscan2
- OTX2 | c.442C>T p.P148S (on ENST00000408990 / NM_172337.3; = p.P156S on NM_021728.4) | Missense Mutation (SNP) | VAF 77/529 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1306099663, COSV59766130; called by muse, mutect2, varscan2
- PAK5 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV62021306; called by muse, mutect2
- PAK5 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 57/390 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV62021843; called by muse, mutect2, varscan2
- PATZ1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 99/585 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.188); catalogued as COSV53231366; called by muse, mutect2, varscan2
- PCDH10 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 80/498 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV52096450; called by muse, mutect2, varscan2
- PCDH15 | c.5462C>T p.P1821L | Missense Mutation (SNP) | VAF 56/446 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1474035683; called by muse, varscan2
- PCDHA2 | c.2050G>A p.V684M | Missense Mutation (SNP) | VAF 15/470 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.2); catalogued as rs1307311865; called by muse, mutect2
- PCDHB3 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV50569134; called by muse, mutect2, varscan2
- PCDHGA1 | c.1960C>T p.L654F | Missense Mutation (SNP) | VAF 136/627 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs149280390; called by muse, mutect2, varscan2
- PCIF1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 64/424 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65026661; called by muse, mutect2, varscan2
- PCLO | c.6121G>A p.E2041K | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV61665653; called by muse, mutect2, varscan2
- PCNX1 | c.6470C>T p.S2157L | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs1285722706, COSV53103899; called by muse, mutect2, varscan2
- PDE1A | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 50/363 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs758316258, COSV59522837, COSV59523042; called by muse, mutect2, varscan2
- PIK3AP1 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs775458651; called by muse, mutect2, varscan2
- PIK3C2G | c.3836C>T p.S1279L (on ENST00000676171; = p.S1238L on NM_004570.5) | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs935135637, COSV56800636, COSV56812711; called by muse, mutect2, varscan2
- PINLYP | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 76/448 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as rs1223494720; called by muse, mutect2, varscan2
- PIP5K1C | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 52/377 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58955626; called by muse, mutect2, varscan2
- PKD1L2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs761159631; called by muse, mutect2, varscan2
- PLCL1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV101406804, COSV70820576; called by muse, mutect2, varscan2
- PLCL2 | c.1006C>T p.H336Y (on ENST00000615277 / NM_001144382.2; = p.H210Y on NM_015184.5) | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.424); catalogued as COSV67621802; called by muse, mutect2, varscan2
- PLXNA4 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs776771552; called by muse, mutect2, varscan2
- PNISR | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.031); catalogued as rs1412595912; called by muse, mutect2, varscan2
- PNP | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs769652649, COSV64092413; called by muse, mutect2, varscan2
- PPP1R9B | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 91/511 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as rs369069780; called by muse, mutect2, varscan2
- PRB2 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 47/422 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.029); catalogued as rs1406802435; called by mutect2, varscan2
- PRB2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 244/793 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.031); catalogued as rs199748368; called by muse, varscan2
- PRUNE2 | c.6008C>T p.S2003L | Missense Mutation (SNP) | VAF 55/394 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV65045590; called by muse, mutect2, varscan2
- PSG4 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 46/451 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs769167488, COSV54935644; called by muse, mutect2
- PTPRC | c.975G>A p.W325* | Nonsense Mutation (SNP) | VAF 21/190 reads (11%) | catalogued as COSV61407507; called by muse, mutect2, varscan2
- PTPRD | c.2262G>A p.M754I | Missense Mutation (SNP) | VAF 66/361 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV61939357, COSV61957177; called by muse, mutect2, varscan2
- PTPRQ | c.1292C>T p.S431L (on ENST00000616559; = p.S389L on NM_001145026.2) | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.236); catalogued as COSV57044307, COSV57056215; called by muse, mutect2, varscan2
- PTPRQ | c.4475G>A p.W1492* (on ENST00000616559; = p.W1450* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 68/377 reads (18%) | catalogued as rs985717064; called by muse, mutect2, varscan2
- PXDNL | c.2981G>A p.G994E | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867225480, COSV62485869; called by muse, mutect2, varscan2
- RAP1GAP | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780792995; called by muse, mutect2, varscan2
- RDX | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV58192981; called by muse, mutect2, varscan2
- RELN | c.7610G>A p.G2537E | Missense Mutation (SNP) | VAF 62/377 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765712159, COSV59004881; called by muse, mutect2, varscan2
- RELN | c.6124G>A p.E2042K | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1204453130, COSV59033497; called by muse, mutect2, varscan2
- REV1 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51483504, COSV51487300; called by muse, mutect2, varscan2
- RGL4 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 70/427 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV51945667; called by muse, mutect2, varscan2
- RGS6 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.066); catalogued as COSV59579870; called by muse, mutect2, varscan2
- RIMS2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 71/417 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1358288737; called by muse, mutect2, varscan2
- RMDN2 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769643888, COSV100636536; called by muse, mutect2, varscan2
- ROBO2 | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1211392180; called by muse, mutect2, varscan2
- RPTN | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 90/543 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533377838; called by muse, mutect2, varscan2
- RTTN | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99733911; called by muse, mutect2, varscan2
- SAGE1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV61013059; called by muse, mutect2, varscan2
- SCAPER | c.2984A>G p.N995S | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1236006985; called by muse, mutect2, varscan2
- SCGB2A2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs141248780; called by muse, mutect2, varscan2
- SCN11A | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772145472; called by muse, mutect2, varscan2
- SCN1A | c.2949C>T p.V983= (on ENST00000303395 / NM_001202435.3; = p.V972= on NM_006920.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 38/199 reads (19%) | catalogued as COSV57670414; called by muse, mutect2, varscan2
- SDK2 | c.6163C>T p.Q2055* | Nonsense Mutation (SNP) | VAF 31/214 reads (14%) | catalogued as rs1229671690; called by muse, mutect2, varscan2
- SERPINA12 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs200162086, COSV57944055; called by muse, mutect2, varscan2
- SFRP4 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 65/399 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV101460899; called by muse, mutect2, varscan2
- SIPA1L1 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62170856; called by muse, mutect2, varscan2
- SLC13A1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.794); catalogued as COSV52009893; called by muse, mutect2, varscan2
- SLC16A14 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV54616939, COSV54621166; called by muse, varscan2
- SLC24A3 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1469471144; called by muse, mutect2, varscan2
- SLC38A1 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs145483756, COSV67064177; called by muse, mutect2, varscan2
- SLC38A10 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 104/491 reads (21%) | catalogued as rs753821644; called by muse, mutect2, varscan2
- SLC4A3 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs373254743, COSV56092158; called by muse, mutect2, varscan2
- SLC6A19 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58671415; called by muse, mutect2, varscan2
- SLC9A4 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54835976; called by muse, varscan2
- SLIT3 | c.628C>T p.L210= | Splice Region (SNP) | VAF 44/299 reads (15%) | catalogued as COSV60622272; called by muse, mutect2, varscan2
- SLITRK1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV65675639; called by muse, mutect2, varscan2
- SLX4 | c.3161C>T p.S1054L | Missense Mutation (SNP) | VAF 78/475 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs373091194; called by muse, mutect2, varscan2
- SMC1B | c.300G>A p.G100= | Splice Region (SNP) | VAF 33/234 reads (14%) | catalogued as rs1010835919, COSV100663383; called by muse, mutect2, varscan2
- SPATA5 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 69/416 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56772565; called by muse, mutect2, varscan2
- STAC | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as COSV99830449; called by muse, mutect2, varscan2
- STARD13 | c.2122C>T p.H708Y (on ENST00000336934 / NM_001243476.3; = p.H590Y on NM_052851.3) | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV55230363; called by muse, mutect2, varscan2
- STXBP5L | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.63); catalogued as COSV56534504; called by muse, mutect2, varscan2
- STYXL1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs782034758; called by muse, mutect2, varscan2
- SUSD2 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 88/734 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1460551402; called by muse, mutect2, varscan2
- SUSD4 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 59/424 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as rs1414323522; called by muse, mutect2, varscan2
- SYN1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55981870; called by muse, mutect2, varscan2
- SYNJ1 | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as COSV59147044; called by muse, mutect2, varscan2
- SYNJ1 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 48/238 reads (20%) | catalogued as rs1037489715, COSV100449332, COSV59156798; called by muse, mutect2, varscan2
- TAF1L | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 110/632 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs868817574, COSV54258058, COSV99644315; called by muse, mutect2, varscan2
- TAF1L | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 94/607 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs34787787, COSV54263729; called by muse, mutect2, varscan2
- TBX4 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 70/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs150233337, COSV53605661; called by muse, mutect2, varscan2
- TEX26 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.728); catalogued as rs1175930398; called by muse, mutect2, varscan2
- TEX33 | c.275C>T p.S92F (on ENST00000381821 / NM_001163857.2; = p.S7F on NM_178552.4) | Missense Mutation (SNP) | VAF 58/491 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as rs1466741719; called by muse, mutect2, varscan2
- THSD7A | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 75/472 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs935456770, COSV70263729; called by muse, mutect2, varscan2
- THSD7B | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 62/322 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs761915500; called by muse, mutect2, varscan2
- TKFC | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs751849872; called by muse, mutect2, varscan2
- TLL1 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.119); catalogued as rs150952504; called by muse, mutect2, varscan2
- TMEM131 | c.5537C>T p.S1846F | Missense Mutation (SNP) | VAF 74/542 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as rs1469186108; called by muse, mutect2, varscan2
- TMEM132C | c.3211G>A p.V1071M | Missense Mutation (SNP) | VAF 71/460 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs1316607548; called by muse, mutect2, varscan2
- TMEM183A | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.463); catalogued as rs578118005; called by muse, mutect2, varscan2
- TPTE | c.1037G>A p.G346E (on ENST00000618007 / NM_199261.4; = p.G328E on NM_199259.4) | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752996568; called by muse, mutect2
- TRIM9 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.715); catalogued as rs1222434797, COSV53626241; called by muse, mutect2, varscan2
- TTK | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs200382179, COSV100036003; called by muse, mutect2, varscan2
- TTN | c.17815C>T p.L5939F (on ENST00000591111; = p.L5012F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/379 reads (15%) | PolyPhen probably damaging (0.999); catalogued as rs747713653, COSV59986328; called by muse, mutect2, varscan2
- TTN | c.6328G>A p.E2110K (on ENST00000591111; = p.E2064K on NM_003319.4) | Missense Mutation (SNP) | VAF 36/514 reads (7%) | PolyPhen benign (0.173); catalogued as COSV59863794, COSV60079795; called by muse, mutect2
- UBE2H | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs778682033, COSV62920323; called by muse, mutect2, varscan2
- UGT2B4 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200618140, COSV59320255; called by muse, mutect2, varscan2
- UGT3A2 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as rs1043591700; called by muse, mutect2, varscan2
- UNC13C | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52882907; called by muse, mutect2, varscan2
- USF2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 74/411 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs1299781845; called by muse, mutect2, varscan2
- USH2A | c.14912G>A p.R4971Q | Missense Mutation (SNP) | VAF 59/384 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776924838; called by muse, mutect2, varscan2
- VCAN | c.7690C>A p.L2564I | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV99035219; called by muse, mutect2, varscan2
- VIT | c.1583C>T p.S528F (on ENST00000389975 / NM_001177969.1; = p.S543F on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64896025; called by muse, mutect2, varscan2
- VNN1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.029); catalogued as rs778413672; called by muse, mutect2, varscan2
- VWA5A | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV64411971; called by muse, mutect2, varscan2
- VWCE | c.1882+1G>A p.X628_splice | Splice Site (SNP) | VAF 54/319 reads (17%) | catalogued as rs1477206141; called by muse, mutect2, varscan2
- XPO4 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs867218131; called by muse, mutect2, varscan2
- ZBED9 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 83/513 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as COSV71729617; called by muse, mutect2, varscan2
- ZC3H13 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 91/520 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.719); catalogued as rs778492328, COSV54450980, COSV99668579; called by muse, mutect2, varscan2
- ZCWPW1 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs372969841; called by muse, mutect2, varscan2
- ZDBF2 | c.5165G>A p.R1722Q | Missense Mutation (SNP) | VAF 35/424 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775009737, COSV100984466; called by muse, mutect2
- ZFPM2 | c.3278G>A p.G1093E | Missense Mutation (SNP) | VAF 103/487 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV65873257, COSV99059188; called by muse, mutect2, varscan2
- ZFYVE16 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs756250610, COSV62015299; called by muse, mutect2, varscan2
- ZNF230 | c.1176T>A p.Y392* | Nonsense Mutation (SNP) | VAF 55/442 reads (12%) | catalogued as rs1199337972; called by muse, mutect2, varscan2
- ZNF318 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 66/410 reads (16%) | catalogued as rs986755957, COSV58935002; called by muse, mutect2, varscan2
- ZNF536 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 106/607 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV62830554; called by muse, mutect2, varscan2
- ZNF536 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 94/552 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs765534247, COSV62826758; called by muse, mutect2, varscan2
- ZNF541 | c.2756C>T p.P919L | Missense Mutation (SNP) | VAF 51/415 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV54544245; called by muse, mutect2
- ZNF541 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54544456; called by muse, mutect2, varscan2
- ZNF71 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs776719783, COSV60149103; called by muse, mutect2, varscan2
- ZNF711 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 97/271 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99034846; called by muse, mutect2, varscan2
- ZNF713 | c.133C>T p.R45* (on ENST00000633730 / NM_001366796.2; = p.R58* on NM_182633.3) | Nonsense Mutation (SNP) | VAF 59/368 reads (16%) | catalogued as rs973963811, COSV68887998; called by muse, mutect2, varscan2
- ZNF727 | c.962T>G p.F321C | Missense Mutation (SNP) | VAF 61/366 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99076615; called by muse, mutect2, varscan2
- ZNF75A | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 72/432 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs769203719; called by muse, mutect2, varscan2
- ZNF79 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 47/351 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61071356; called by muse, mutect2, varscan2
- ZNF83 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 69/517 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1291115034; called by muse, mutect2, varscan2
- ZNF880 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 73/478 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101424993, COSV69905910; called by muse, mutect2, varscan2
- ZRANB3 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 53/325 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1352476022; called by muse, mutect2, varscan2
- ABCA13 | c.8387G>T p.S2796I | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCA9 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ABCB1 | c.78T>A p.D26E | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABCB1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- ABHD4 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ABTB2 | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 54/372 reads (15%) | called by muse, mutect2, varscan2
- AC099489.1 | c.7180G>A p.D2394N | Missense Mutation (SNP) | VAF 80/401 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ACACB | c.3238C>T p.P1080S | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACCS | c.190del p.S64Pfs*6 | Frame Shift Del (DEL) | VAF 48/348 reads (14%) | called by mutect2, pindel*, varscan2
- ACSM4 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADAM17 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2
- ADAMTS2 | c.2797A>T p.T933S | Missense Mutation (SNP) | VAF 76/511 reads (15%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- ADGRF2 | c.1478C>T p.A493V (on ENST00000296862 / NM_001368115.2; = p.A425V on NM_153839.7) | Missense Mutation (SNP) | VAF 82/479 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRF3 | c.2179G>C p.G727R (on ENST00000311519 / NM_001145168.1; = p.G528R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/445 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ADGRV1 | c.15699G>A p.M5233I | Missense Mutation (SNP) | VAF 116/530 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADNP | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 60/458 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADRA1A | c.695T>G p.V232G | Missense Mutation (SNP) | VAF 84/515 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- AFF2 | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- AK7 | c.2000G>T p.R667I | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ALAD | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 59/418 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ALDH18A1 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.4583C>T p.S1528F | Missense Mutation (SNP) | VAF 52/350 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); called by muse, varscan2
- ANK3 | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, varscan2
- ANKAR | c.2204G>A p.W735* | Nonsense Mutation (SNP) | VAF 28/258 reads (11%) | called by muse, mutect2, varscan2
- ANKRD18A | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 76/479 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD33 | c.470C>T p.S157L (on ENST00000340970 / NM_001304459.2; = p.S282L on NM_182608.4) | Missense Mutation (SNP) | VAF 98/559 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ANKS1B | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AOX1 | c.3567G>A p.M1189I | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2
- APOB | c.5166C>A p.D1722E | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- ARFGEF3 | c.6142G>A p.E2048K | Missense Mutation (SNP) | VAF 85/517 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGAP29 | c.2666C>T p.S889F | Missense Mutation (SNP) | VAF 54/429 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ARHGAP6 | c.594T>A p.D198E | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ASIC4 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.169); called by muse, mutect2
- ATP2B2 | c.2995G>A p.E999K (on ENST00000352432; = p.E965K on NM_001683.5) | Missense Mutation (SNP) | VAF 48/573 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- BEX5 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- BHMT2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 74/431 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP7 | c.623T>A p.L208H | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- BNC1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 91/505 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRINP1 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 51/451 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BTBD11 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 60/419 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- BTN3A1 | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 145/562 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BVES | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- C12orf56 | c.261T>G p.D87E | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C1orf94 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 103/545 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2CD2 | c.2066G>A p.G689D | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C2orf16 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CAND1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 45/281 reads (16%) | called by muse, mutect2, varscan2
- CASR | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 106/432 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCDC189 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CD19 | c.1517G>A p.G506E (on ENST00000324662 / NM_001178098.2; = p.G505E on NM_001770.6) | Missense Mutation (SNP) | VAF 61/476 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CD28 | c.411G>A p.G137= | Splice Region (SNP) | VAF 46/230 reads (20%) | called by muse, mutect2, varscan2
- CDH18 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 76/412 reads (18%) | called by muse, mutect2, varscan2
- CDH22 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CEP57 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFAP54 | c.3446C>T p.A1149V | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2
- CHMP7 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CHRDL1 | c.662G>A p.G221E (on ENST00000372045; = p.G227E on NM_145234.4) | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CILP | c.3197C>T p.P1066L | Missense Mutation (SNP) | VAF 91/536 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CILP2 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 68/424 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- CIT | c.5312C>T p.S1771F | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CLDN34 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 118/304 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN7 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIC3 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CMYA5 | c.8111G>A p.G2704E | Missense Mutation (SNP) | VAF 93/550 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL12A1 | c.6343G>A p.G2115R | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- COL13A1 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL22A1 | c.3664G>C p.G1222R | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL4A5 | c.2945G>A p.G982D | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 87/441 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A3 | c.7369G>A p.E2457K | Missense Mutation (SNP) | VAF 68/397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COLEC10 | c.222A>T p.G74= | Splice Region (SNP) | VAF 68/266 reads (26%) | called by muse, mutect2, varscan2
- COLEC11 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CPAMD8 | c.962G>A p.G321E (on ENST00000651564; = p.G274E on NM_015692.5) | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CPXCR1 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CRACDL | c.2867A>T p.D956V | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRTC3 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 64/434 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CSHL1 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CSMD2 | c.4591C>T p.L1531F | Missense Mutation (SNP) | VAF 80/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CSMD3 | c.8711G>A p.G2904E (on ENST00000297405 / NM_001363185.1; = p.G2735E on NM_052900.3) | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTAGE1 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 86/517 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CUBN | c.9429G>A p.W3143* | Nonsense Mutation (SNP) | VAF 62/361 reads (17%) | called by muse, mutect2, varscan2
- CWF19L2 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DISP2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, varscan2
- DMBT1 | c.5459G>A p.G1820E (on ENST00000338354 / NM_001377530.1; = p.G1063E on NM_004406.3) | Missense Mutation (SNP) | VAF 98/644 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH6 | c.10553G>A p.G3518E | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.5107G>A p.E1703K | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOCK3 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 30/333 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- DOCK3 | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.071); called by muse, mutect2
- DPF1 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- DUOX1 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- DUXB | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DZIP1 | c.2509G>A p.G837R (on ENST00000347108; = p.G818R on NM_014934.5) | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.23); called by muse, mutect2
- ECPAS | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- EHD4 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EIF4G2 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- FAM133B | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- FAM133B | c.465G>A p.K155= | Splice Region (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- FAM135B | c.1363T>C p.S455P | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- FAM3B | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 52/413 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT3 | c.11032C>T p.L3678F | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FAT4 | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 76/464 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBLN2 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 36/560 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.829); called by muse, mutect2
- FHOD3 | c.3527G>C p.W1176S (on ENST00000359247 / NM_001281739.3; = p.W1193S on NM_025135.5) | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRAS1 | c.10673C>T p.T3558I | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- GADL1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GALNT5 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 73/407 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GIMAP8 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 68/411 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- GNAZ | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 76/445 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- GPRC5C | c.422G>A p.G141E (on ENST00000652232; = p.G96E on NM_018653.4) | Missense Mutation (SNP) | VAF 65/522 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GZMA | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 85/439 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HCFC2 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 81/446 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- HDAC3 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEYL | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 121/604 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HID1 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- HNF1B | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 44/413 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- HPS1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSDL1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 75/487 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- HSPA1L | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 194/798 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2
- HYDIN | c.12029C>T p.S4010F | Missense Mutation (SNP) | VAF 56/445 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IFT122 | c.2119C>T p.H707Y (on ENST00000348417 / NM_052989.3; = p.H648Y on NM_018262.4) | Missense Mutation (SNP) | VAF 78/349 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGFN1 | c.1396G>A p.E466K (on ENST00000295591 / NM_001367841.1; = p.E2923K on NM_001164586.2) | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGLV1-51 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- INAVA | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- INHBA | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 81/419 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IRX1 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 82/547 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- ITGA8 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JCAD | c.3232C>T p.P1078S | Missense Mutation (SNP) | VAF 63/428 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- KALRN | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KARS1 | c.1613A>C p.E538A | Missense Mutation (SNP) | VAF 72/459 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KARS1 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 72/457 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KATNAL2 | c.719T>G p.V240G (on ENST00000356157 / NM_001353899.1; = p.V168G on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- KCNA5 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 77/557 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- KCNB2 | c.2278A>T p.T760S | Missense Mutation (SNP) | VAF 78/453 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ3 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 34/441 reads (8%) | called by muse, mutect2
- KCNRG | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 81/446 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- KCNS2 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 80/459 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCTD19 | c.643+1G>C p.X215_splice | Splice Site (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- KIAA1217 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 71/378 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF3C | c.1709T>A p.L570H | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- KMT2B | c.7391T>C p.L2464P | Missense Mutation (SNP) | VAF 52/363 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KRT32 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA1 | c.6163C>T p.Q2055* | Nonsense Mutation (SNP) | VAF 45/337 reads (13%) | called by muse, mutect2, varscan2
- LAMC3 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LAT | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LMX1B | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 76/515 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- LPIN1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- LRP1B | c.12043G>A p.G4015S | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRP1B | c.4948_4949dup p.S1650Rfs*6 | Frame Shift Ins (INS) | VAF 27/216 reads (13%) | called by mutect2, pindel, varscan2
- LRRC4B | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 72/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LY9 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 47/399 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MAGEA8 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1A | c.5557C>T p.P1853S | Missense Mutation (SNP) | VAF 16/449 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- MARF1 | c.3982C>T p.L1328F | Missense Mutation (SNP) | VAF 67/399 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEX3D | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 110/661 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MGAM | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 76/549 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- MINDY4B | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MINK1 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 78/540 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPP4 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MPRIP | c.920T>G p.F307C | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- MROH2A | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- MROH9 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MTMR4 | c.1675C>T p.H559Y | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- MTUS1 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MTUS2 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MUC12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 85/440 reads (19%) | SIFT tolerated, low confidence (0.29); called by muse, mutect2, varscan2
- MUC16 | c.11171C>T p.P3724L | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC3A | c.353C>G p.T118S | Missense Mutation (SNP) | VAF 59/407 reads (14%) | SIFT deleterious, low confidence (0.04); called by mutect2, varscan2
- MYH7 | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 65/384 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO3B | c.3466C>T p.H1156Y | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.029); called by muse, mutect2
- NAPRT | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 106/523 reads (20%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- NAV2 | c.707C>A p.P236Q | Missense Mutation (SNP) | VAF 87/484 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAXE | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 92/486 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NECTIN2 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 74/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NECTIN4 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC3 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 85/548 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NLRP4 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 65/428 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NOP14 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NOS3 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 99/499 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- NPFFR2 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 90/521 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPR2 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- NPTX2 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 103/528 reads (20%) | called by muse, mutect2, varscan2
- NT5DC3 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 47/315 reads (15%) | called by muse, mutect2, varscan2
- NUTM1 | c.1281G>A p.V427= | Splice Region (SNP) | VAF 35/265 reads (13%) | called by muse, mutect2, varscan2
- NUTM2G | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 87/457 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXPH1 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 95/515 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NYNRIN | c.4811C>T p.S1604F | Missense Mutation (SNP) | VAF 81/447 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ODF3L2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 90/583 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, varscan2
- OR4K15 | c.535C>T p.H179Y (on ENST00000305051; = p.H155Y on NM_001005486.1) | Missense Mutation (SNP) | VAF 85/474 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR51D1 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 92/495 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR5G3 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- OSGEP | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- OTOGL | c.5576T>A p.I1859N (on ENST00000547103; = p.I1850N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- P2RY12 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 101/309 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PAPLN | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PAPLN | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PAPLN | c.830C>T p.P277L (on ENST00000554301; = p.P250L on NM_173462.4) | Missense Mutation (SNP) | VAF 53/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA10 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 114/464 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- PCDHA2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 134/575 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- PCDHGB1 | c.1678T>C p.Y560H | Missense Mutation (SNP) | VAF 94/435 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PCYT1B | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- PEG3 | c.567G>A p.R189= | Splice Region (SNP) | VAF 32/271 reads (12%) | called by muse, mutect2, varscan2
- PIEZO2 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PIK3C2B | c.3838G>A p.G1280S | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- PIK3R5 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIWIL4 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.8924G>A p.G2975E | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, varscan2
- PLIN4 | c.182G>A p.W61* (on ENST00000301286; = p.W76* on NM_001367868.2) | Nonsense Mutation (SNP) | VAF 103/555 reads (19%) | called by muse, mutect2, varscan2
- PLXNA4 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PNPLA3 | c.1215C>T p.S405= | Splice Region (SNP) | VAF 39/295 reads (13%) | called by muse, mutect2, varscan2
- POMC | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 88/490 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POU4F2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 64/410 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PPFIA1 | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PRAMEF26 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PRB2 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 150/697 reads (22%) | called by muse, mutect2, varscan2
- PRH2 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 91/1318 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- PRH2 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 90/1318 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); called by muse, mutect2
- PRIMPOL | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR29 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 62/416 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSAP | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 74/405 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PSG6 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PTPRQ | c.1909C>T p.P637S (on ENST00000616559; = p.P595S on NM_001145026.2) | Missense Mutation (SNP) | VAF 57/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PTPRR | c.1243C>A p.H415N | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAB11FIP4 | c.1421T>C p.L474P | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RAD51AP2 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAG2 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 71/505 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA2 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 58/429 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RASGRP2 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 38/321 reads (12%) | called by muse, mutect2, varscan2
- RBM7 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RELB | c.1175C>A p.P392Q | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- RGS6 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RNF43 | c.944A>C p.N315T | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- ROR1 | c.1381C>G p.P461A | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ROR1 | c.2786C>T p.T929I | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RP1 | c.4025G>A p.G1342E | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- RPS27AP5 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 93/422 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- RREB1 | c.1176del p.Q392Hfs*19 | Frame Shift Del (DEL) | VAF 60/624 reads (10%) | called by mutect2, pindel
- RRH | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RSPH10B2 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 54/650 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RTN4 | c.3184C>T p.Q1062* (on ENST00000337526 / NM_020532.5; = p.Q69* on NM_007008.3) | Nonsense Mutation (SNP) | VAF 44/294 reads (15%) | called by muse, mutect2, varscan2
- RUFY4 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- SAMD9 | c.3709G>A p.D1237N | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SFMBT1 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SGSM2 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 49/379 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SH2D3C | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 103/503 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC12A5 | c.284C>T p.P95L (on ENST00000454036 / NM_001134771.2; = p.P72L on NM_020708.5) | Missense Mutation (SNP) | VAF 47/350 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC16A14 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- SLC35G2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC38A11 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC5A7 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A8 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 75/436 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SLFN12 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 59/351 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SLFN14 | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 87/447 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SMC1B | c.3086C>T p.T1029I | Missense Mutation (SNP) | VAF 61/342 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SMG6 | c.3412C>T p.L1138F | Missense Mutation (SNP) | VAF 67/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNAP25 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX4 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 92/313 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SPAG17 | c.6584G>T p.G2195V | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- SPRY3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 117/690 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, varscan2
- SSU72P2 | c.438A>T p.E146D | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2
- SSU72P2 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 40/508 reads (8%) | called by muse, mutect2
- STK31 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- STOML1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 92/522 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- STYX | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SYCP2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAAR5 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 78/397 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TAP2 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 44/668 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.367); called by muse, mutect2
- TARBP1 | c.2906C>T p.S969F | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TAS2R14 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 73/621 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCP11 | c.606G>A p.M202I (on ENST00000512012; = p.M140I on NM_018679.5) | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM2 | c.6941A>G p.N2314S (on ENST00000518659 / NM_001122679.2; = p.N2075S on NM_001080428.3) | Missense Mutation (SNP) | VAF 81/514 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TET1 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 53/476 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TEX13D | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.24); called by muse, varscan2
- TIAM2 | c.4180G>A p.E1394K (on ENST00000529824; = p.E1365K on NM_012454.3) | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TM6SF1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132D | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TMEM177 | c.110T>A p.F37Y | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2
- TNIP2 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 92/539 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- TRABD2B | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 69/475 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAPPC3L | c.503T>G p.F168C | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV10 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRAV16 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TRAV8-6 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TRBV2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TRIM49B | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, varscan2
- TRMT5 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRNP1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TRPM3 | c.198G>A p.W66* (on ENST00000357533 / NM_001366142.2; = p.W35* on NM_001007471.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 59/296 reads (20%) | called by muse, mutect2, varscan2
- TRPM6 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPV5 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 73/551 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TTN | c.75920G>A p.G25307E (on ENST00000591111; = p.G17883E on NM_003319.4) | Missense Mutation (SNP) | VAF 76/358 reads (21%) | PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TTN | c.47188G>A p.G15730R (on ENST00000591111; = p.G8306R on NM_003319.4) | Missense Mutation (SNP) | VAF 21/319 reads (7%) | PolyPhen probably damaging (0.992); called by muse, mutect2
- TTN | c.40747G>A p.E13583K (on ENST00000591111; = p.E6159K on NM_003319.4) | Missense Mutation (SNP) | VAF 63/401 reads (16%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.27608C>T p.S9203F (on ENST00000591111; = p.S8276F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/424 reads (9%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.26425G>A p.G8809R (on ENST00000591111; = p.G7882R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/319 reads (12%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.12581C>T p.S4194L (on ENST00000591111; = p.S4148L on NM_003319.4) | Missense Mutation (SNP) | VAF 67/389 reads (17%) | called by muse, mutect2, varscan2
- TYRP1 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 73/443 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UGT1A10 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 50/505 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT1A8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 70/390 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UGT2B4 | c.1530dup p.C511Mfs*10 | Frame Shift Ins (INS) | VAF 36/308 reads (12%) | called by mutect2, pindel, varscan2
- USP24 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WDFY4 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- WNK2 | c.2861C>T p.P954L | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- WNK2 | c.6231G>A p.W2077* (on ENST00000297954 / NM_001282394.1; = p.W2040* on NM_006648.3) | Nonsense Mutation (SNP) | VAF 25/240 reads (10%) | called by muse, mutect2, varscan2
- XPO4 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ZBTB43 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ZC3H12C | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 41/360 reads (11%) | called by muse, mutect2, varscan2
- ZCCHC2 | c.1257T>G p.N419K | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ZGRF1 | c.2450C>T p.S817L | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZKSCAN5 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 83/443 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF597 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF705G | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 60/868 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); called by muse, mutect2
- ZNF728 | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 48/257 reads (19%) | called by muse, mutect2, varscan2
- ZNF804A | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF98 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ZSWIM6 | c.3409C>T p.P1137S | Missense Mutation (SNP) | VAF 93/513 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA6 | c.2175C>T p.S725= | Silent (SNP) | VAF 58/315 reads (18%) | called by muse, mutect2, varscan2
- ABCA7 | c.2556C>T p.S852= | Silent (SNP) | VAF 55/279 reads (20%) | called by muse, mutect2, varscan2
- ABCC1 | c.4416C>T p.I1472= | Silent (SNP) | VAF 72/467 reads (15%) | called by muse, mutect2, varscan2
- ABCC12 | c.2007T>C p.D669= | Silent (SNP) | VAF 24/259 reads (9%) | called by muse, mutect2, varscan2
- ACR | c.435C>T p.L145= | Silent (SNP) | VAF 87/535 reads (16%) | catalogued as rs756365879; called by muse, mutect2, varscan2
- ADAM8 | c.399G>A p.V133= | Silent (SNP) | VAF 62/440 reads (14%) | catalogued as rs1356212280; called by muse, mutect2, varscan2
- ADAMTS18 | c.894C>T p.L298= | Silent (SNP) | VAF 67/440 reads (15%) | catalogued as rs748153604, COSV51417591; called by muse, mutect2, varscan2
- ADGRB3 | c.4461C>T p.V1487= | Silent (SNP) | VAF 34/339 reads (10%) | catalogued as COSV53261980; called by muse, mutect2, varscan2
- ADK | c.780G>A p.E260= (on ENST00000286621; = p.E243= on NM_001123.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/272 reads (17%) | called by muse, mutect2, varscan2
- ADRA2B | c.24C>T p.S8= | Silent (SNP) | VAF 32/224 reads (14%) | catalogued as rs1347428227, COSV101337337; called by muse, mutect2, varscan2
- AGPS | c.1953C>T p.I651= | Silent (SNP) | VAF 50/278 reads (18%) | called by muse, mutect2, varscan2
- AKAP9 | c.5787G>A p.E1929= (on ENST00000359028; = p.E1897= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/343 reads (16%) | called by muse, mutect2, varscan2
- AKR1B10 | c.750C>T p.I250= | Silent (SNP) | VAF 56/382 reads (15%) | catalogued as COSV62054935; called by muse, mutect2, varscan2
- ALDH3B1 | c.120C>T p.N40= | Silent (SNP) | VAF 75/471 reads (16%) | called by muse, mutect2, varscan2
- APOB | c.5271G>A p.L1757= | Silent (SNP) | VAF 62/365 reads (17%) | called by muse, varscan2
- ARMC3 | c.1764G>A p.K588= | Silent (SNP) | VAF 39/290 reads (13%) | called by muse, mutect2, varscan2
- ATP11C | c.615C>T p.I205= | Silent (SNP) | VAF 53/198 reads (27%) | catalogued as rs780655017, COSV59567422; called by muse, mutect2, varscan2
- ATP9B | c.2730C>T p.F910= | Silent (SNP) | VAF 95/433 reads (22%) | called by muse, mutect2, varscan2
- ATXN7 | c.1812C>T p.V604= | Silent (SNP) | VAF 80/373 reads (21%) | called by muse, mutect2, varscan2
- AVPR1B | c.759C>T p.S253= | Silent (SNP) | VAF 80/421 reads (19%) | called by muse, mutect2, varscan2
- B3GNT2 | c.159C>T p.T53= | Silent (SNP) | VAF 73/396 reads (18%) | called by muse, mutect2, varscan2
- BLNK | c.909C>T p.I303= | Silent (SNP) | VAF 43/274 reads (16%) | called by muse, mutect2, varscan2
- BNIPL | c.213C>T p.T71= | Silent (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- C10orf67 | c.1356C>T p.V452= | Silent (SNP) | VAF 50/291 reads (17%) | called by muse, mutect2, varscan2
- C11orf86 | c.225G>A p.L75= | Silent (SNP) | VAF 56/447 reads (13%) | catalogued as rs1313357655; called by muse, mutect2, varscan2
- C17orf64 | c.267G>A p.G89= | Silent (SNP) | VAF 53/327 reads (16%) | catalogued as rs1434649227; called by muse, mutect2, varscan2
- C7 | c.1125G>A p.P375= | Silent (SNP) | VAF 65/365 reads (18%) | catalogued as rs1269582660; called by muse, mutect2, varscan2
- CACNA1C | c.5409G>A p.R1803= | Silent (SNP) | VAF 142/442 reads (32%) | called by muse, mutect2, varscan2
- CACNA1G | c.273C>T p.I91= | Silent (SNP) | VAF 58/342 reads (17%) | catalogued as rs1440729254; called by muse, mutect2, varscan2
- CCDC40 | c.2487C>T p.I829= | Silent (SNP) | VAF 66/420 reads (16%) | catalogued as rs372937081; called by muse, mutect2, varscan2
- CCDC60 | c.750C>T p.P250= | Silent (SNP) | VAF 73/458 reads (16%) | called by muse, mutect2, varscan2
- CDIPT | c.594C>T p.A198= | Silent (SNP) | VAF 42/403 reads (10%) | catalogued as rs768718112; called by muse, mutect2, varscan2
- CENPE | c.6852G>A p.K2284= | Silent (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2, varscan2
- CETN1 | c.150G>A p.A50= | Silent (SNP) | VAF 69/503 reads (14%) | catalogued as rs1388207245, COSV59120868; called by muse, mutect2, varscan2
- CFHR4 | c.1341C>T p.F447= (on ENST00000367416 / NM_001201551.2; = p.F201= on NM_006684.5) | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as COSV52225228; called by muse, mutect2, varscan2
- CLTCL1 | c.4383G>A p.K1461= | Silent (SNP) | VAF 66/316 reads (21%) | called by muse, mutect2, varscan2
- COLQ | c.126G>A p.Q42= | Silent (SNP) | VAF 38/414 reads (9%) | called by muse, mutect2
- CRYBG2 | c.4605T>C p.N1535= | Silent (SNP) | VAF 24/213 reads (11%) | called by muse, mutect2, varscan2
- CSF2RB | c.2160C>T p.T720= | Silent (SNP) | VAF 85/465 reads (18%) | catalogued as rs1311170881; called by muse, mutect2, varscan2
- CSMD3 | c.7893C>T p.S2631= (on ENST00000297405 / NM_001363185.1; = p.S2527= on NM_052900.3) | Silent (SNP) | VAF 40/218 reads (18%) | catalogued as COSV52296338; called by muse, mutect2, varscan2
- CSNKA2IP | c.1566C>T p.I522= | Silent (SNP) | VAF 95/398 reads (24%) | called by muse, mutect2, varscan2
- CTBP1 | c.927C>T p.N309= | Silent (SNP) | VAF 54/374 reads (14%) | called by muse, mutect2, varscan2
- CYP1A1 | c.61C>T p.L21= | Silent (SNP) | VAF 61/367 reads (17%) | catalogued as rs761407107; called by muse, mutect2, varscan2
- CYP2C18 | c.807C>T p.I269= | Silent (SNP) | VAF 33/170 reads (19%) | called by muse, mutect2, varscan2
- CYTH3 | c.543C>T p.P181= | Silent (SNP) | VAF 33/228 reads (14%) | catalogued as rs879155222; called by muse, mutect2, varscan2
- DACT2 | c.966C>T p.V322= | Silent (SNP) | VAF 100/526 reads (19%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.132C>T p.F44= | Silent (SNP) | VAF 57/378 reads (15%) | called by muse, mutect2, varscan2
- DHCR7 | c.669C>T p.I223= | Silent (SNP) | VAF 56/392 reads (14%) | catalogued as rs879926326; called by muse, mutect2, varscan2
- DHX9 | c.1566C>T p.F522= | Silent (SNP) | VAF 37/211 reads (18%) | called by muse, mutect2, varscan2
- DIO2 | c.702G>A p.Q234= | Silent (SNP) | VAF 69/501 reads (14%) | called by muse, mutect2, varscan2
- DIP2B | c.3822C>T p.I1274= | Silent (SNP) | VAF 47/312 reads (15%) | catalogued as rs766420539, COSV56593657; called by muse, mutect2, varscan2
- DLGAP2 | c.66G>A p.R22= | Silent (SNP) | VAF 40/284 reads (14%) | called by muse, mutect2, varscan2
- DNAH10 | c.7341A>G p.E2447= (on ENST00000409039; = p.E2386= on NM_207437.3) | Silent (SNP) | VAF 42/309 reads (14%) | called by muse, mutect2, varscan2
- DNAH2 | c.12936C>T p.I4312= | Silent (SNP) | VAF 66/406 reads (16%) | catalogued as rs781622877, COSV101209548; called by muse, mutect2, varscan2
- DOCK4 | c.5475C>T p.T1825= | Silent (SNP) | VAF 50/317 reads (16%) | called by mutect2, varscan2
- DSCAML1 | c.2844C>T p.P948= (on ENST00000321322; = p.P888= on NM_020693.4) | Silent (SNP) | VAF 47/273 reads (17%) | catalogued as rs768622272; called by muse, mutect2, varscan2
- DSG2 | c.1935C>T p.T645= | Silent (SNP) | VAF 53/350 reads (15%) | called by muse, mutect2, varscan2
- DSP | c.8286G>A p.Q2762= | Silent (SNP) | VAF 21/589 reads (4%) | called by muse, mutect2
- E2F8 | c.495G>A p.E165= | Silent (SNP) | VAF 73/433 reads (17%) | called by muse, mutect2, varscan2
- EFCAB12 | c.268C>T p.L90= | Silent (SNP) | VAF 82/445 reads (18%) | called by muse, mutect2, varscan2
- EGFL8 | c.546C>T p.T182= | Silent (SNP) | VAF 26/826 reads (3%) | called by muse, mutect2
- ELAPOR1 | c.1620C>T p.I540= | Silent (SNP) | VAF 59/405 reads (15%) | called by muse, mutect2, varscan2
- ELOVL5 | c.681C>T p.F227= | Silent (SNP) | VAF 70/404 reads (17%) | catalogued as rs1336181255; called by muse, mutect2, varscan2
- EML1 | c.2412G>A p.G804= | Silent (SNP) | VAF 73/334 reads (22%) | called by muse, mutect2, varscan2
- ESPN | c.4026C>T p.C1342= | Silent (SNP) | VAF 55/337 reads (16%) | catalogued as rs551669727; called by muse, mutect2, varscan2
- EYS | c.7320C>T p.F2440= | Silent (SNP) | VAF 54/426 reads (13%) | called by muse, mutect2, varscan2
- F5 | c.2292C>T p.F764= | Silent (SNP) | VAF 67/394 reads (17%) | catalogued as rs536614946, COSV63124055; called by muse, mutect2, varscan2
- FAM117B | c.1542C>T p.L514= | Silent (SNP) | VAF 30/446 reads (7%) | catalogued as rs938931875, COSV57419677, COSV57423091; called by muse, mutect2
- FAM135B | c.3378C>T p.F1126= | Silent (SNP) | VAF 55/385 reads (14%) | catalogued as rs267601784, COSV52745765; called by muse, mutect2, varscan2
- FAM162B | c.228C>T p.I76= | Silent (SNP) | VAF 50/298 reads (17%) | called by muse, mutect2, varscan2
- FAM166A | c.192C>T p.F64= | Silent (SNP) | VAF 92/452 reads (20%) | catalogued as rs752201959; called by muse, mutect2, varscan2
- FAM184B | c.1974G>A p.Q658= | Silent (SNP) | VAF 63/455 reads (14%) | called by muse, mutect2, varscan2
- FAM187B | c.696C>T p.L232= | Silent (SNP) | VAF 43/289 reads (15%) | catalogued as rs914780937, COSV61201812; called by muse, varscan2
- FAM71B | c.756G>A p.T252= | Silent (SNP) | VAF 83/471 reads (18%) | catalogued as rs144904764, COSV100262112; called by muse, mutect2, varscan2
- FAT2 | c.2575C>T p.L859= | Silent (SNP) | VAF 84/438 reads (19%) | called by muse, mutect2, varscan2
- FER1L6 | c.5376C>T p.P1792= | Silent (SNP) | VAF 40/292 reads (14%) | called by muse, mutect2, varscan2
- FGD2 | c.984G>A p.K328= | Silent (SNP) | VAF 63/426 reads (15%) | called by muse, mutect2, varscan2
- FLG | c.7494G>A p.Q2498= | Silent (SNP) | VAF 99/639 reads (15%) | catalogued as rs141241616; called by muse, mutect2, varscan2
- FREM3 | c.2463C>T p.F821= | Silent (SNP) | VAF 98/553 reads (18%) | called by muse, mutect2, varscan2
- GABRA6 | c.1275C>T p.F425= | Silent (SNP) | VAF 96/507 reads (19%) | catalogued as rs901284552; called by muse, mutect2, varscan2
- GABRG3 | c.495C>T p.L165= | Silent (SNP) | VAF 39/293 reads (13%) | called by muse, mutect2, varscan2
- GALNT17 | c.753C>T p.F251= | Silent (SNP) | VAF 36/281 reads (13%) | called by muse, mutect2, varscan2
- GATM | c.612C>T p.F204= | Silent (SNP) | VAF 63/397 reads (16%) | catalogued as COSV67540112; called by muse, mutect2, varscan2
- GBA | c.852C>T p.P284= | Silent (SNP) | VAF 63/421 reads (15%) | called by muse, mutect2, varscan2
- GFRA1 | c.795C>T p.T265= | Silent (SNP) | VAF 34/285 reads (12%) | catalogued as rs1476373131; called by muse, mutect2, varscan2
- GJA1 | c.264C>T p.P88= | Silent (SNP) | VAF 72/422 reads (17%) | catalogued as rs766836780, COSV99246886; called by muse, mutect2, varscan2
- GLI2 | c.1482G>A p.S494= (on ENST00000361492 / NM_001374353.1; = p.S511= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs200507501; called by muse, mutect2
- GNS | c.1341T>C p.A447= | Silent (SNP) | VAF 36/309 reads (12%) | called by muse, mutect2, varscan2
- GPR158 | c.1371G>A p.T457= | Silent (SNP) | VAF 44/289 reads (15%) | catalogued as rs1175352427, COSV100892907, COSV66264628; called by muse, mutect2, varscan2
- GPR42 | c.591G>A p.L197= | Silent (SNP) | VAF 8/267 reads (3%) | called by muse, mutect2
- GRAMD1A | c.501C>T p.I167= | Silent (SNP) | VAF 105/647 reads (16%) | called by muse, mutect2, varscan2
269 further variants in this file (0 protein-altering or splice-affecting, 233 silent, 36 other) are not listed here.
